Somatic mutation profile of tumor specimen C3L-00081-01 (aliquot CPT0001020005) from CPTAC case C3L-00081, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.0 years (22,629 days).
Specimen C3L-00081-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97b013dd-89a4-492c-aed5-67edd4996965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00081-31 (Blood Derived Normal), aliquot CPT0000010163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/878957e3-f4c4-49c4-af12-5fb5727a4af8

The open-access MAF lists 397 somatic variants for this specimen: 256 protein-altering or splice-affecting, 89 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 89, Intron 27, Nonsense Mutation 12, 3'UTR 10, Frame Shift Del 9, Splice Site 7, RNA 7, 5'UTR 5, 3'Flank 3, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 214/381 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1609C>A p.R537S | Missense Mutation (SNP) | VAF 292/511 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as CM032804; called by muse, mutect2, varscan2
- AC011005.1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 231/629 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as rs748622301, COSV71956032; called by muse, mutect2, varscan2
- ACTRT2 | c.830C>G p.S277W | Missense Mutation (SNP) | VAF 141/273 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1336865916, COSV65760235; called by muse, mutect2, varscan2
- ADAM2 | c.2005A>T p.R669* | Nonsense Mutation (SNP) | VAF 48/135 reads (36%) | catalogued as rs1284326615; called by muse, mutect2, varscan2
- ADGRG2 | c.1612T>A p.S538T (on ENST00000379869 / NM_001079858.3; = p.S535T on NM_005756.4) | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV61338732; called by muse, mutect2
- AKAP9 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs746325120; called by muse, mutect2, varscan2
- ANXA6 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100637076; called by muse, mutect2, varscan2
- APBA2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 161/406 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); catalogued as rs756243157; called by muse, mutect2, varscan2
- ARHGAP35 | c.4336G>A p.G1446S | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as rs777545082; called by muse, mutect2, varscan2
- ARMC5 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV51659570; called by muse, mutect2, varscan2
- ASCL1 | c.388C>A p.R130S | Missense Mutation (SNP) | VAF 101/176 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99901887; called by muse, mutect2, varscan2
- AXIN2 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs778612433, COSV61056738; ClinVar: uncertain significance; called by muse, mutect2
- BCORL1 | c.2515G>A p.A839T | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as rs781411863; called by muse, mutect2, varscan2
- C1orf159 | c.1051C>T p.R351W (on ENST00000379339 / NM_001330306.2; = p.R169W on NM_017891.5) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs763525638, COSV53879440; called by muse, mutect2
- CDH10 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99077798; called by muse, mutect2, varscan2
- CDX2 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.113); catalogued as COSV101122712; called by muse, mutect2, varscan2
- CHEK1 | c.940T>G p.Y314D | Missense Mutation (SNP) | VAF 129/174 reads (74%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1370402981; called by muse, mutect2, varscan2
- COL6A5 | c.7504G>A p.D2502N (on ENST00000312481; = p.D2498N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs752185068, COSV99593495; called by muse, mutect2, varscan2
- CRP | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54813375; called by muse, mutect2, varscan2
- DGKK | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1243687601; called by muse, mutect2
- DMD | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 39/288 reads (14%) | catalogued as COSV63776196; called by muse, mutect2, varscan2
- DNAH6 | c.11663A>C p.Q3888P | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as rs1328249936; called by muse, mutect2, varscan2
- DPP10 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59661325; called by muse, mutect2
- DYNC1H1 | c.5885G>T p.R1962L | Missense Mutation (SNP) | VAF 161/381 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518287, CM152586; called by muse, mutect2, varscan2
- F13B | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 134/527 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66372373, COSV66375457; called by muse, mutect2, varscan2
- FAM110A | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 38/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55726786; called by muse, mutect2
- FAT1 | c.6745del p.A2249Hfs*4 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | catalogued as COSV71673750; called by mutect2, pindel, varscan2
- FBN2 | c.5846A>G p.K1949R | Missense Mutation (SNP) | VAF 156/276 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV99327519; called by muse, mutect2, varscan2
- FBN2 | c.4929del p.I1644Sfs*5 | Frame Shift Del (DEL) | VAF 149/341 reads (44%) | catalogued as COSV99329536; called by mutect2, pindel, varscan2
- GALR1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55318099; called by muse, mutect2, varscan2
- GFER | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs760018110; called by muse, mutect2, varscan2
- GIP | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.992); catalogued as COSV100656925; called by muse, mutect2, varscan2
- GOLGA6L7 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1398034387, COSV101629706; called by muse, mutect2, varscan2
- GYPC | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 91/414 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs772372126; called by muse, mutect2, varscan2
- GYPC | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 93/419 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs745993366, COSV52148468; called by muse, mutect2, varscan2
- HOXA6 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 160/533 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as rs368790713; called by muse, mutect2, varscan2
- ITGA11 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs773471766; called by muse, mutect2, varscan2
- KAT6B | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99767639; called by muse, mutect2, varscan2
- KCNH7 | c.1598G>T p.R533L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59783478; called by muse, mutect2, varscan2
- KCTD13 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 33/356 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs750765239; called by muse, mutect2
- KDR | c.3187G>C p.G1063R | Missense Mutation (SNP) | VAF 135/410 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55765273; called by muse, varscan2
- KEAP1 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50282385; called by muse, mutect2, varscan2
- KIF15 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as rs534270094, COSV58160448; called by muse, mutect2, varscan2
- KIF16B | c.3622-1G>C p.X1208_splice | Splice Site (SNP) | VAF 88/300 reads (29%) | catalogued as COSV100734893; called by muse, mutect2, varscan2
- KIR2DL1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs113536578, COSV52415400; called by muse, mutect2, varscan2
- KMT2B | c.5900C>T p.P1967L | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55860116; called by muse, mutect2, varscan2
- KRTAP9-1 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 210/668 reads (31%) | SIFT tolerated (0.09); catalogued as rs147741483; called by muse, mutect2, varscan2
- LEF1 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as COSV99489981; called by muse, mutect2, varscan2
- LHX4 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 93/246 reads (38%) | catalogued as COSV55377860; called by muse, mutect2, varscan2
- MAGEB6 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.208); catalogued as rs1016060428, COSV66872464; called by muse, mutect2
- MAML1 | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 166/316 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV99483314; called by muse, mutect2, varscan2
- MCM9 | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 152/368 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as rs1161025470; called by muse, mutect2, varscan2
- MDGA1 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.061); catalogued as rs760270151; called by muse, mutect2, varscan2
- MROH2B | c.4057C>A p.L1353M | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV68181653; called by muse, mutect2, varscan2
- MYH13 | c.3418C>A p.R1140S | Missense Mutation (SNP) | VAF 108/190 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52827387; called by muse, mutect2, varscan2
- NDUFA10 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 190/470 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs764730363; called by muse, mutect2, varscan2
- NLRP12 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 340/922 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60747324; called by muse, mutect2, varscan2
- NOL6 | c.3050G>A p.R1017H | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs767961563; called by muse, mutect2, varscan2
- NOS3 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.264); catalogued as rs1460122551; called by muse, mutect2, varscan2
- NOTO | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV68260564; called by muse, mutect2, varscan2
- NT5C1B | c.1373G>T p.C458F (on ENST00000359846 / NM_001199086.2; = p.C398F on NM_033253.4) | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV58397802; called by muse, mutect2, varscan2
- OR8H1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 137/190 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs1369006802, COSV57293417; called by muse, mutect2, varscan2
- PARP8 | c.2149A>G p.N717D | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.686); catalogued as COSV55861708; called by muse, mutect2, varscan2
- PCDH1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 104/184 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs1366429431, COSV54619225; called by muse, mutect2, varscan2
- PCGF3 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1029081275; called by muse, mutect2, varscan2
- PIK3C2G | c.3083G>C p.G1028A (on ENST00000676171; = p.G987A on NM_004570.5) | Missense Mutation (SNP) | VAF 137/194 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56809899; called by muse, mutect2, varscan2
- PLCB3 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs759550537; called by muse, mutect2, varscan2
- RAD21 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV52056634; called by muse, varscan2
- RP1L1 | c.6355C>T p.P2119S | Missense Mutation (SNP) | VAF 106/540 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs183636715; called by muse, mutect2, varscan2
- RYR2 | c.12739G>C p.A4247P | Missense Mutation (SNP) | VAF 230/647 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as COSV100772058; called by muse, mutect2, varscan2
- SBSN | c.1688C>A p.T563K (on ENST00000452271 / NM_001166034.2; = p.T220K on NM_198538.4) | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772418905, COSV71733038; called by muse, mutect2, varscan2
- SCG2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59541488; called by muse, mutect2, varscan2
- SLC9B1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 104/1884 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56469913, COSV56475587; called by muse, mutect2
- SMARCAD1 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV62775066, COSV62775332; called by muse, mutect2, varscan2
- SMIM9 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1313670230; called by muse, mutect2, varscan2
- SNRPN | c.305del p.G102Efs*40 | Frame Shift Del (DEL) | VAF 26/165 reads (16%) | catalogued as COSV57600489; called by mutect2, pindel, varscan2
- SORBS1 | c.953G>T p.R318L (on ENST00000361941 / NM_001034954.2; = p.R154L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53357097; called by muse, varscan2
- SPATA31D1 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 167/604 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.712); catalogued as COSV61201007; called by muse, mutect2, varscan2
- SSTR2 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59535128; called by muse, mutect2, varscan2
- ST18 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52492134; called by muse, mutect2, varscan2
- STRA8 | c.373G>C p.E125Q (on ENST00000275764; = p.E103Q on NM_182489.2) | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as rs760950896; called by muse, mutect2, varscan2
- TANC2 | c.4136A>T p.Q1379L | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV67337229; called by muse, mutect2, varscan2
- TENM3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV69311040; called by muse, mutect2, varscan2
- TLR4 | c.639C>A p.N213K (on ENST00000355622 / NM_138554.5; = p.N173K on NM_003266.4) | Missense Mutation (SNP) | VAF 89/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371871286, COSV100790704; called by muse, mutect2, varscan2
- TMEM98 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.266); catalogued as COSV99912809; called by muse, mutect2, varscan2
- TMPRSS13 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 174/535 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV70625997; called by muse, mutect2, varscan2
- TNFSF9 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99832386; called by muse, mutect2, varscan2
- TRPS1 | c.2453C>T p.S818F (on ENST00000220888 / NM_001330599.2; = p.S831F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 305/566 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV55263586; called by muse, mutect2, varscan2
- TXNDC2 | c.544G>A p.A182T (on ENST00000306084 / NM_001098529.2; = p.A115T on NM_032243.6) | Missense Mutation (SNP) | VAF 152/390 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.136); catalogued as rs750179467, COSV60151657; called by muse, varscan2
- UQCRH | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 198/356 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs762474674, COSV61177417; called by muse, mutect2, varscan2
- VPS9D1 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101231956; called by muse, mutect2, varscan2
- ZNF230 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 121/383 reads (32%) | catalogued as COSV101432149; called by muse, mutect2, varscan2
- ZNF728 | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1037862372; called by muse, mutect2, varscan2
- ZNF835 | c.952A>G p.S318G | Missense Mutation (SNP) | VAF 123/326 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.598); catalogued as rs999319701, COSV73379404, COSV73379718; called by muse, mutect2, varscan2
- ABCC8 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 224/331 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ACTN4 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 66/368 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, varscan2
- ADGRB2 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- AK5 | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- AKAP11 | c.1148C>A p.S383* | Nonsense Mutation (SNP) | VAF 97/236 reads (41%) | called by muse, mutect2, varscan2
- AMOT | c.2474-2A>C p.X825_splice (on ENST00000371959 / NM_001113490.1; = p.X416_splice on NM_133265.3) | Splice Site (SNP) | VAF 20/54 reads (37%) | called by muse, varscan2
- ARAP1 | c.4122G>A p.W1374* (on ENST00000393609 / NM_001040118.2; = p.W1129* on NM_015242.4) | Nonsense Mutation (SNP) | VAF 76/796 reads (10%) | called by muse, mutect2
- ARL6 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ASXL2 | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ATP1B4 | c.1009A>T p.I337L (on ENST00000218008 / NM_001142447.3; = p.I333L on NM_012069.5) | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ATP8A2 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- BNIP3L | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- BRWD1 | c.3226del p.I1076Lfs*12 | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | called by mutect2, pindel, varscan2
- C1orf116 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C2CD3 | c.2799dup p.P934Afs*4 | Frame Shift Ins (INS) | VAF 65/287 reads (23%) | called by mutect2, pindel, varscan2
- CACNA1H | c.4082A>T p.Q1361L | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CCDC7 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 82/148 reads (55%) | called by muse, mutect2, varscan2
- CDH4 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDK16 | c.1454-8C>T | Splice Region (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CGB8 | c.174C>G p.C58W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CHD8 | c.6703G>T p.A2235S (on ENST00000646647 / NM_001170629.2; = p.A1956S on NM_020920.4) | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CHMP4C | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CIDEA | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLN8 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CNGA2 | c.83del p.G28Afs*42 | Frame Shift Del (DEL) | VAF 97/302 reads (32%) | called by mutect2, pindel, varscan2
- COL5A3 | c.2805del p.P936Lfs*58 | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- CSRP1 | c.182G>C p.C61S | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTPS1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 109/212 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CUBN | c.4130G>C p.R1377P | Missense Mutation (SNP) | VAF 213/401 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CUBN | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 129/280 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- DENND4B | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DLC1 | c.4395G>T p.L1465F (on ENST00000276297 / NM_001348081.2; = p.L1028F on NM_006094.5) | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DMD | c.4028A>T p.E1343V | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- DNAAF6 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH5 | c.4386C>A p.D1462E | Missense Mutation (SNP) | VAF 176/544 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DRP2 | c.2440G>T p.A814S | Missense Mutation (SNP) | VAF 125/351 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUS3L | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DYRK4 | c.78G>C p.E26D | Missense Mutation (SNP) | VAF 148/200 reads (74%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EBF3 | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, varscan2
- EIF2AK4 | c.1690_1691del p.V564Yfs*3 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- EPHA10 | c.750C>A p.S250R | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHA4 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 111/524 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ESCO2 | c.1652G>A p.R551K | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- EXT2 | c.788C>T p.P263L (on ENST00000343631; = p.P296L on NM_000401.3) | Missense Mutation (SNP) | VAF 322/447 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.119); called by muse, varscan2
- F5 | c.4297C>T p.L1433F | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, mutect2
- FAM169A | c.-1G>A | Splice Region (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- FBXO4 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FLNA | c.7497C>G p.I2499M (on ENST00000369850 / NM_001110556.2; = p.I2491M on NM_001456.3) | Missense Mutation (SNP) | VAF 146/493 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLNA | c.5440A>G p.K1814E (on ENST00000369850 / NM_001110556.2; = p.K1806E on NM_001456.3) | Missense Mutation (SNP) | VAF 175/590 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FOXR2 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- FRY | c.5202T>A p.Y1734* | Nonsense Mutation (SNP) | VAF 146/389 reads (38%) | called by muse, mutect2, varscan2
- FSCB | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, varscan2
- GAPVD1 | c.4061T>A p.V1354E (on ENST00000394104; = p.V1363E on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GASK1A | c.249G>T p.L83F | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- GET3 | c.409A>G p.S137G | Missense Mutation (SNP) | VAF 112/193 reads (58%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GLIS1 | c.176A>G p.E59G | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- GNG3 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 246/358 reads (69%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- GSDMA | c.200del p.G67Afs*33 | Frame Shift Del (DEL) | VAF 72/238 reads (30%) | called by mutect2, pindel, varscan2
- HAL | c.660A>T p.K220N | Missense Mutation (SNP) | VAF 119/225 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HCFC1 | c.3932G>T p.G1311V | Missense Mutation (SNP) | VAF 137/527 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- HDAC9 | c.3181G>A p.E1061K (on ENST00000441542 / NM_178425.3; = p.E1058K on NM_178423.3) | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HLA-DQA1 | c.398G>T p.C133F | Missense Mutation (SNP) | VAF 239/349 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMX3 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HNF4G | c.939del p.M314Wfs*13 (on ENST00000354370 / NM_001330561.2; = p.M361Wfs*13 on NM_004133.5) | Frame Shift Del (DEL) | VAF 140/318 reads (44%) | called by mutect2, pindel, varscan2
- IGKV1-8 | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 175/593 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- IL10RB | c.299G>C p.W100S | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL26 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- INPP4A | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- IRS4 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 236/773 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IRS4 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IRX1 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- JMJD4 | c.755A>G p.K252R | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCND1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- KCNH7 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1217 | c.2761C>G p.Q921E | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KLHDC4 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL4 | c.1729G>C p.G577R | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KPNA5 | c.1083G>C p.W361C | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP10-4 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 249/465 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- KRTAP9-1 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 208/663 reads (31%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- LAMB1 | c.4963G>A p.V1655M | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LARGE1 | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- LARGE1 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- LILRB2 | c.1326G>C p.Q442H | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- LOX | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 86/150 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRP1 | c.6869A>C p.Y2290S | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAGEB18 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MAGEC1 | c.3144G>T p.W1048C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MAGEE1 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 148/449 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MGAM2 | c.4088C>A p.P1363Q | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MSLNL | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- MTTP | c.982A>G p.N328D | Missense Mutation (SNP) | VAF 180/590 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2
- MUC5AC | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 110/169 reads (65%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- MYH1 | c.3597G>T p.K1199N | Missense Mutation (SNP) | VAF 216/389 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYLK | c.3023T>A p.V1008E | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NACC2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NAGA | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 158/399 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NAP1L3 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.968); called by muse, varscan2
- NBPF20 | c.1747G>A p.E583K (on ENST00000369373; = p.E238K on NM_001278267.1) | Missense Mutation (SNP) | VAF 80/540 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NCOA1 | c.3827G>C p.G1276A | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NDN | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN4X | c.1373A>T p.D458V | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NLRP12 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 172/536 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- OGN | c.41T>A p.V14E | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OR2T2 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 98/532 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR2T35 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- OR5H15 | c.677T>C p.L226S | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARD3B | c.2315T>C p.V772A (on ENST00000406610 / NM_001302769.2; = p.V710A on NM_152526.6) | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- PBXIP1 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 103/361 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDHGA5 | c.1988C>A p.A663D | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCLO | c.11183C>T p.P3728L | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDLIM7 | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PDZD4 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PHKA1 | c.1636G>T p.D546Y | Missense Mutation (SNP) | VAF 145/510 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- PHOX2B | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); called by muse, varscan2
- PIK3CG | c.2204A>G p.Q735R | Missense Mutation (SNP) | VAF 144/464 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- PKHD1L1 | c.8540T>G p.L2847* | Nonsense Mutation (SNP) | VAF 15/464 reads (3%) | called by muse, mutect2
- POLN | c.1458+1G>A p.X486_splice | Splice Site (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- PORCN | c.1054C>A p.L352M (on ENST00000326194 / NM_203475.3; = p.L341M on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/492 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, varscan2
- PORCN | c.1055T>G p.L352R (on ENST00000326194 / NM_203475.3; = p.L341R on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- PPFIA1 | c.1301G>T p.R434M | Missense Mutation (SNP) | VAF 719/887 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PPL | c.1178A>T p.Y393F | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKDC | c.11489G>T p.S3830I | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PSMD10 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK7 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 88/154 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PYGL | c.2178-1G>T p.X726_splice | Splice Site (SNP) | VAF 55/209 reads (26%) | called by muse, mutect2, varscan2
- RALGAPB | c.2072A>T p.Q691L | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RGS7 | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 142/531 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RLBP1 | c.662G>T p.R221M | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- RNF144A | c.241-1G>C p.X81_splice | Splice Site (SNP) | VAF 42/148 reads (28%) | called by muse, varscan2
- RNF148 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RYR2 | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SEMA5B | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- SFTPB | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 211/546 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC2A14 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 27/241 reads (11%) | PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SLC4A8 | c.2756T>C p.L919P | Missense Mutation (SNP) | VAF 103/169 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A8 | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPTBN4 | c.208T>A p.W70R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRF | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SUGT1 | c.329-1G>A p.X110_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- TBC1D2B | c.988A>C p.S330R | Missense Mutation (SNP) | VAF 186/476 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TCEAL1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, varscan2
- TCEAL4 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 148/473 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TET2 | c.5222C>A p.P1741Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TMEM207 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 68/419 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TRIM45 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 85/141 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TSC22D2 | c.2242C>T p.Q748* | Nonsense Mutation (SNP) | VAF 193/688 reads (28%) | called by muse, mutect2, varscan2
- TSPAN5 | c.279+1G>C p.X93_splice | Splice Site (SNP) | VAF 87/289 reads (30%) | called by muse, mutect2, varscan2
- TTBK2 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 99/441 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TWIST2 | c.169A>G p.S57G | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UTRN | c.3374A>T p.E1125V | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFAND6 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFP3 | c.271A>T p.S91C | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIC3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- ZIK1 | c.1371C>A p.H457Q | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF425 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF853 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ABCA6 | c.3708C>G p.P1236= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as COSV99447010; called by muse, mutect2, varscan2
- ABCA6 | c.2460C>T p.F820= | Silent (SNP) | VAF 70/200 reads (35%) | called by muse, mutect2, varscan2
- ABCB10 | c.735T>C p.N245= | Silent (SNP) | VAF 103/311 reads (33%) | catalogued as rs1177482647; called by muse, mutect2, varscan2
- AF196969.1 | c.261C>T p.Y87= | Silent (SNP) | VAF 20/209 reads (10%) | catalogued as rs145509273, COSV99339333; called by muse, mutect2
- ANO4 | c.2280A>G p.L760= (on ENST00000392977 / NM_001286615.2; = p.L725= on NM_178826.4) | Silent (SNP) | VAF 52/109 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.342T>A p.T114= | Silent (SNP) | VAF 104/300 reads (35%) | catalogued as COSV53644843; called by muse, mutect2, varscan2
- BICC1 | c.2865G>T p.A955= | Silent (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- CASR | c.2781C>T p.S927= (on ENST00000490131; = p.S1004= on NM_000388.4) | Silent (SNP) | VAF 155/743 reads (21%) | catalogued as rs1249991104; called by muse, mutect2, varscan2
- CDH10 | c.1887A>G p.V629= | Silent (SNP) | VAF 95/172 reads (55%) | catalogued as COSV52573120; called by muse, mutect2, varscan2
- CDH10 | c.621C>A p.P207= | Silent (SNP) | VAF 52/238 reads (22%) | called by muse, mutect2, varscan2
- CELSR3 | c.1788C>T p.D596= | Silent (SNP) | VAF 49/236 reads (21%) | called by muse, mutect2, varscan2
- CEP19 | c.249G>A p.G83= | Silent (SNP) | VAF 154/607 reads (25%) | catalogued as COSV56359862; called by muse, mutect2, varscan2
- CLPB | c.1584C>T p.V528= | Silent (SNP) | VAF 218/1008 reads (22%) | called by muse, varscan2
- CLPB | c.1476C>T p.I492= | Silent (SNP) | VAF 179/916 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.5115C>A p.G1705= (on ENST00000297405 / NM_001363185.1; = p.G1601= on NM_052900.3) | Silent (SNP) | VAF 68/390 reads (17%) | catalogued as COSV52167279, COSV99835799; called by muse, varscan2
- DCAF12L2 | c.888C>T p.S296= | Silent (SNP) | VAF 71/211 reads (34%) | catalogued as COSV63582133, COSV63583009; called by muse, mutect2, varscan2
- DPYS | c.399G>T p.V133= | Silent (SNP) | VAF 89/441 reads (20%) | called by muse, mutect2, varscan2
- EVC | c.2136G>A p.E712= | Silent (SNP) | VAF 136/316 reads (43%) | called by muse, mutect2, varscan2
- EXTL3 | c.1845C>G p.P615= | Silent (SNP) | VAF 59/150 reads (39%) | called by muse, mutect2, varscan2
- FAM217B | c.612C>T p.G204= | Silent (SNP) | VAF 118/287 reads (41%) | catalogued as COSV62564686; called by muse, mutect2, varscan2
- FANCM | c.2997G>A p.P999= | Silent (SNP) | VAF 152/499 reads (30%) | catalogued as rs141430587; called by muse, mutect2, varscan2
- FPR1 | c.75G>C p.L25= | Silent (SNP) | VAF 78/216 reads (36%) | called by muse, mutect2, varscan2
- GNPTAB | c.2559A>T p.T853= | Silent (SNP) | VAF 62/138 reads (45%) | called by muse, mutect2, varscan2
- GOLGA8T | c.618G>A p.T206= | Silent (SNP) | VAF 145/681 reads (21%) | catalogued as rs772328723; called by muse, mutect2, varscan2
- GUCY1A2 | c.2198G>A p.*733= | Silent (SNP) | VAF 113/166 reads (68%) | called by muse, varscan2
- HCRT | c.105C>T p.P35= | Silent (SNP) | VAF 97/256 reads (38%) | catalogued as rs752188193; called by muse, varscan2
- IGF2BP1 | c.621G>T p.V207= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- ITIH1 | c.1083C>T p.G361= | Silent (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- KL | c.2110C>T p.L704= | Silent (SNP) | VAF 60/156 reads (38%) | called by muse, mutect2, varscan2
- KLC1 | c.552A>G p.E184= | Silent (SNP) | VAF 87/294 reads (30%) | catalogued as rs201009117; called by muse, mutect2, varscan2
- LSAMP | c.453G>T p.L151= | Silent (SNP) | VAF 103/424 reads (24%) | called by muse, mutect2, varscan2
- MAB21L1 | c.942G>A p.R314= | Silent (SNP) | VAF 95/231 reads (41%) | catalogued as COSV100080370; called by muse, mutect2, varscan2
- MAGEA11 | c.666A>G p.L222= | Silent (SNP) | VAF 139/444 reads (31%) | catalogued as COSV100290767; called by muse, mutect2, varscan2
- MCOLN2 | c.213G>A p.L71= | Silent (SNP) | VAF 47/78 reads (60%) | called by muse, mutect2, varscan2
- MIA | c.90G>A p.L30= | Silent (SNP) | VAF 107/333 reads (32%) | called by muse, mutect2, varscan2
- MIGA1 | c.939T>C p.F313= | Silent (SNP) | VAF 71/136 reads (52%) | called by muse, mutect2, varscan2
- MKRN3 | c.300C>T p.I100= | Silent (SNP) | VAF 133/327 reads (41%) | catalogued as rs1337381352, COSV100090566; called by muse, mutect2, varscan2
- MROH2B | c.4056C>A p.G1352= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as COSV68182201; called by muse, mutect2, varscan2
- MROH5 | c.1257G>A p.K419= | Silent (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- NAT14 | c.123G>A p.R41= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2
- NDN | c.639G>T p.V213= | Silent (SNP) | VAF 40/170 reads (24%) | called by muse, mutect2, varscan2
- NHSL2 | c.21G>T p.T7= | Silent (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- NR4A3 | c.450G>A p.P150= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100432134; called by muse, mutect2, varscan2
- OR2M4 | c.477G>A p.V159= | Silent (SNP) | VAF 58/182 reads (32%) | called by muse, mutect2, varscan2
- OR5AN1 | c.120G>T p.L40= | Silent (SNP) | VAF 141/217 reads (65%) | catalogued as COSV100004364; called by muse, mutect2, varscan2
- OR5L2 | c.744C>A p.I248= | Silent (SNP) | VAF 62/189 reads (33%) | called by muse, mutect2, varscan2
- OTOA | c.3132C>T p.D1044= (on ENST00000286149; = p.D1030= on NM_144672.4) | Silent (SNP) | VAF 87/493 reads (18%) | called by muse, mutect2, varscan2
- OTOG | c.2232C>T p.C744= | Silent (SNP) | VAF 190/262 reads (73%) | catalogued as rs768421997, COSV68042505; called by muse, mutect2, varscan2
- PHACTR3 | c.856C>A p.R286= | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as COSV63034721; called by muse, mutect2, varscan2
- PLCB1 | c.2892C>A p.A964= | Silent (SNP) | VAF 92/396 reads (23%) | catalogued as COSV62052119; called by muse, varscan2
- PLPPR4 | c.1206G>T p.R402= | Silent (SNP) | VAF 110/203 reads (54%) | catalogued as COSV64566119; called by muse, mutect2, varscan2
- PLXNB2 | c.3933G>C p.V1311= | Silent (SNP) | VAF 197/426 reads (46%) | called by muse, mutect2, varscan2
- PLXNB3 | c.192C>G p.G64= | Silent (SNP) | VAF 87/376 reads (23%) | called by muse, mutect2, varscan2
- POTEM | c.171C>A p.L57= | Silent (SNP) | VAF 524/1614 reads (32%) | catalogued as COSV69155670; called by muse, varscan2
- PPP1R2C | c.72G>A p.S24= | Silent (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- PPP4R1 | c.1479G>T p.V493= (on ENST00000400556 / NM_001042388.3; = p.V476= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53283033; called by muse, mutect2, varscan2
- PRDM13 | c.681C>A p.I227= | Silent (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- PRND | c.39C>T p.V13= | Silent (SNP) | VAF 268/551 reads (49%) | catalogued as COSV59896748; called by muse, mutect2, varscan2
- PROKR2 | c.291C>T p.I97= | Silent (SNP) | VAF 24/640 reads (4%) | called by muse, mutect2
- PTCH2 | c.2787G>A p.G929= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs1377417938; called by muse, mutect2, varscan2
- RASSF2 | c.762C>T p.I254= | Silent (SNP) | VAF 97/459 reads (21%) | catalogued as COSV65083036; called by muse, mutect2, varscan2
- REG3G | c.42G>T p.L14= | Silent (SNP) | VAF 79/307 reads (26%) | called by muse, mutect2, varscan2
- RFWD3 | c.1572G>T p.L524= | Silent (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- RIC8A | c.42G>A p.E14= | Silent (SNP) | VAF 189/285 reads (66%) | catalogued as rs752859525; called by muse, mutect2, varscan2
- SBF1 | c.1518C>T p.P506= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- SCG2 | c.738G>A p.G246= | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as rs1315909886, COSV100544875; called by muse, mutect2, varscan2
- SERTAD2 | c.510C>T p.S170= | Silent (SNP) | VAF 143/489 reads (29%) | called by muse, mutect2, varscan2
- SLC30A8 | c.1041C>A p.L347= | Silent (SNP) | VAF 78/462 reads (17%) | called by muse, mutect2, varscan2
- SLIT3 | c.1260G>A p.K420= | Silent (SNP) | VAF 85/138 reads (62%) | called by muse, mutect2, varscan2
- SPAG4 | c.624C>A p.R208= | Silent (SNP) | VAF 102/247 reads (41%) | called by muse, mutect2, varscan2
- SPATA5 | c.1540C>A p.R514= | Silent (SNP) | VAF 53/228 reads (23%) | catalogued as COSV56775436; called by muse, mutect2, varscan2
- SRF | c.1152C>T p.S384= | Silent (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- SWT1 | c.1698G>A p.K566= | Silent (SNP) | VAF 57/207 reads (28%) | catalogued as COSV100833478, COSV62259272; called by muse, mutect2, varscan2
- TCP10L2 | c.183C>T p.L61= | Silent (SNP) | VAF 78/368 reads (21%) | catalogued as rs762138952; called by muse, mutect2, varscan2
- TEP1 | c.4677G>A p.S1559= | Silent (SNP) | VAF 75/144 reads (52%) | catalogued as rs755289769; called by muse, mutect2, varscan2
- THSD1 | c.648C>A p.T216= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV51630396; called by muse, mutect2, varscan2
- TOP2B | c.363G>A p.K121= (on ENST00000264331 / NM_001330700.2; = p.K116= on NM_001068.3) | Silent (SNP) | VAF 59/108 reads (55%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.1045C>T p.L349= | Silent (SNP) | VAF 72/201 reads (36%) | catalogued as rs761646332; called by muse, mutect2, varscan2
- TTC21A | c.1431C>A p.G477= | Silent (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.1056C>A p.A352= | Silent (SNP) | VAF 158/337 reads (47%) | called by muse, mutect2, varscan2
- UBTFL1 | c.309C>T p.P103= | Silent (SNP) | VAF 501/633 reads (79%) | called by muse, mutect2, varscan2
- VCAN | c.3198A>G p.Q1066= | Silent (SNP) | VAF 75/140 reads (54%) | called by muse, mutect2, varscan2
- VRTN | c.633C>T p.C211= | Silent (SNP) | VAF 97/289 reads (34%) | catalogued as rs753601863, COSV56440256; called by muse, mutect2, varscan2
- XRRA1 | c.1998C>T p.P666= | Silent (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- ZBBX | c.1644A>G p.Q548= | Silent (SNP) | VAF 125/218 reads (57%) | catalogued as COSV56783278, COSV56785507; called by muse, mutect2, varscan2
- ZC3H4 | c.2550G>A p.Q850= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as rs1275876036; called by muse, mutect2, varscan2
- ZNF185 | c.1348C>A p.R450= | Silent (SNP) | VAF 107/358 reads (30%) | catalogued as COSV59278507; called by muse, mutect2, varscan2
- ZNF521 | c.909G>T p.V303= | Silent (SNP) | VAF 97/286 reads (34%) | called by muse, mutect2, varscan2
- ZNF831 | c.3726G>T p.A1242= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV64046489; called by muse, mutect2, varscan2
- AC138749.1 | n.1777C>A | RNA (SNP) | VAF 77/530 reads (15%) | catalogued as rs1345017080; called by muse, mutect2, varscan2
- ALB | c.482+10C>A | Intron (SNP) | VAF 32/138 reads (23%) | called by muse, varscan2
- BTBD19 | c.414+397G>T | Intron (SNP) | VAF 70/106 reads (66%) | catalogued as rs1211284155; called by muse, mutect2, varscan2
- CCDC40 | c.1562+2027C>T | Intron (SNP) | VAF 83/242 reads (34%) | called by muse, mutect2, varscan2
- CDK5 | c.-15C>T | 5'UTR (SNP) | VAF 92/242 reads (38%) | catalogued as rs1158626401; called by muse, mutect2, varscan2
- CEACAM1 | c.-96T>A | 5'UTR (SNP) | VAF 98/282 reads (35%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811862 C>T | 3'Flank (SNP) | VAF 72/200 reads (36%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-33349G>C | Intron (SNP) | VAF 35/216 reads (16%) | called by muse, mutect2, varscan2
- DCHS2 | n.3206C>T | RNA (SNP) | VAF 81/171 reads (47%) | called by muse, mutect2, varscan2
- DDX11 | c.2053-26C>A | Intron (SNP) | VAF 231/331 reads (70%) | called by muse, mutect2, varscan2
- DNAJC19 | c.55+33C>T | Intron (SNP) | VAF 377/1451 reads (26%) | catalogued as rs771517436; called by muse, mutect2, varscan2
- DZANK1 | chr20:18381099 C>G | 3'Flank (SNP) | VAF 125/335 reads (37%) | called by muse, mutect2, varscan2
- ERCC3 | c.522-37C>T | Intron (SNP) | VAF 76/161 reads (47%) | called by muse, mutect2, varscan2
- FAM172BP | n.228A>T | RNA (SNP) | VAF 94/306 reads (31%) | called by muse, mutect2, varscan2
- FARP2 | c.1411+807A>G | Intron (SNP) | VAF 82/299 reads (27%) | called by muse, mutect2, varscan2
- FAS | c.*371A>G | 3'UTR (SNP) | VAF 73/216 reads (34%) | called by muse, mutect2, varscan2
- FHL1 | c.*457T>C | 3'UTR (SNP) | VAF 81/283 reads (29%) | called by muse, mutect2, varscan2
- FKTN | c.1045-11C>G | Intron (SNP) | VAF 93/333 reads (28%) | called by muse, mutect2, varscan2
- FMR1 | c.*1117A>G | 3'UTR (SNP) | VAF 74/240 reads (31%) | called by muse, varscan2
- GABRA2 | c.187+17129C>A | Intron (SNP) | VAF 18/104 reads (17%) | called by muse, varscan2
- GCLC | c.1401+59A>G | Intron (SNP) | VAF 87/158 reads (55%) | catalogued as rs1346967957; called by muse, mutect2, varscan2
- GLIS3 | c.*37G>C | 3'UTR (SNP) | VAF 160/291 reads (55%) | catalogued as rs374278034; called by muse, mutect2, varscan2
- GNGT1 | c.-11-39A>T | Intron (SNP) | VAF 92/266 reads (35%) | catalogued as COSV50353381; called by muse, mutect2, varscan2
- GRK2 | c.*909G>T | 3'UTR (SNP) | VAF 96/152 reads (63%) | called by muse, mutect2, varscan2
- IQCH | c.-23G>C | 5'UTR (SNP) | VAF 50/233 reads (21%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-16997T>C | Intron (SNP) | VAF 99/249 reads (40%) | called by muse, mutect2, varscan2
- LINC01205 | n.227+29G>T | Intron (SNP) | VAF 123/256 reads (48%) | called by muse, mutect2, varscan2
- LINC02145 | n.332C>A | RNA (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
- LY6H | c.68-134G>A | Intron (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2
- MIGA2 | c.1459-134G>T | Intron (SNP) | VAF 43/102 reads (42%) | called by muse, varscan2
- MRRFP1 | n.173G>T | RNA (SNP) | VAF 147/485 reads (30%) | called by muse, mutect2, varscan2
- NLRP12 | c.*16G>T | 3'UTR (SNP) | VAF 200/640 reads (31%) | called by muse, mutect2, varscan2
- NLRP12 | c.*15T>C | 3'UTR (SNP) | VAF 204/650 reads (31%) | called by muse, mutect2, varscan2
- NTN5 | c.1105+227C>T | Intron (SNP) | VAF 20/226 reads (9%) | catalogued as rs757211248, COSV54307263; called by muse, mutect2
- PDE4B | c.281+74250A>T | Intron (SNP) | VAF 83/135 reads (61%) | called by muse, mutect2, varscan2
- POLR3H | c.209-917C>T | Intron (SNP) | VAF 43/180 reads (24%) | catalogued as rs1045581762; called by muse, mutect2, varscan2
- PORCN | c.-37-103A>G | Intron (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45226817 T>C | 3'Flank (SNP) | VAF 265/403 reads (66%) | called by muse, mutect2, varscan2
- REG1B | c.*7C>A | 3'UTR (SNP) | VAF 49/166 reads (30%) | called by mutect2, varscan2
- RNF213 | c.10423+9C>T | Intron (SNP) | VAF 27/290 reads (9%) | catalogued as rs373021348; called by muse, mutect2
- SEC63 | c.1500+35G>A | Intron (SNP) | VAF 74/356 reads (21%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.*2252dup | 3'UTR (INS) | VAF 91/218 reads (42%) | called by mutect2, varscan2
- SLC9B1P1 | n.1234C>T | RNA (SNP) | VAF 10/78 reads (13%) | called by mutect2, varscan2
- TCF4 | c.550-22863G>A | Intron (SNP) | VAF 69/224 reads (31%) | called by muse, mutect2, varscan2
- TG | c.6563-12C>A | Intron (SNP) | VAF 120/242 reads (50%) | called by muse, mutect2, varscan2
- THOC3 | c.-47C>T | 5'UTR (SNP) | VAF 68/236 reads (29%) | catalogued as rs1314230692; called by muse, mutect2, varscan2
- UBE2DNL | n.122G>T | RNA (SNP) | VAF 60/136 reads (44%) | called by muse, mutect2, varscan2
- UBE2F | c.214+8573G>A | Intron (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- VAMP4 | c.*5A>G | 3'UTR (SNP) | VAF 11/91 reads (12%) | called by muse, varscan2
- ZNF317 | c.-127G>T | 5'UTR (SNP) | VAF 162/296 reads (55%) | called by muse, mutect2, varscan2
- ZNF76 | c.432+317C>A | Intron (SNP) | VAF 54/85 reads (64%) | called by muse, varscan2
- ZSCAN32 | c.839-883G>T | Intron (SNP) | VAF 107/288 reads (37%) | called by muse, mutect2, varscan2
